Somatic mutation profile of tumor specimen TCGA-25-2404-01A (aliquot TCGA-25-2404-01A-01W-0799-08) from TCGA case TCGA-25-2404, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 38.8 years (14,184 days).
Specimen TCGA-25-2404-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0846cc3a-c42a-4e99-8bd1-674f81cb2a4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2404-10A (Blood Derived Normal), aliquot TCGA-25-2404-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fac195c-dca8-4550-89ee-88fc2bf31b63

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, In Frame Del 3, Nonsense Mutation 2, RNA 1, Intron 1, Nonstop Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 95/120 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369325050; called by muse, mutect2, varscan2
- AHNAK | c.3194C>T p.P1065L | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99948151; called by muse, mutect2
- AMBN | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59825197; called by muse, mutect2, varscan2
- ARHGAP30 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63517565; called by muse, mutect2, varscan2
- ASPRV1 | c.992A>G p.D331G | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100208540; called by muse, mutect2
- ATRX | c.242+1G>A p.X81_splice | Splice Site (SNP) | VAF 77/202 reads (38%) | catalogued as COSV100969547; called by muse, mutect2, varscan2
- CXorf38 | c.492G>C p.E164D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV59947857; called by muse, mutect2, varscan2
- DAB1 | c.1177C>A p.Q393K (on ENST00000371231; = p.Q360K on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.304); catalogued as COSV64690477; called by muse, mutect2
- EGFR | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99292585; called by muse, mutect2, varscan2
- ETNPPL | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56596457, COSV99624910; called by muse, mutect2, varscan2
- GALNT13 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV101223422; called by muse, mutect2, varscan2
- GFRA1 | c.1396T>C p.*466Qext*3 | Nonstop Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100815825; called by muse, mutect2
- GRM8 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100283940; called by muse, mutect2, varscan2
- HMCN1 | c.15315T>G p.C5105W | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99631198; called by muse, mutect2
- IFIT2 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 136/316 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51079645; called by muse, mutect2, varscan2
- KIF4B | c.1822C>G p.Q608E | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV70530244; called by muse, mutect2, varscan2
- KRT33B | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV99290683; called by muse, mutect2
- LRRTM4 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.06); catalogued as COSV69153795; called by muse, mutect2, varscan2
- MBP | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.328); catalogued as rs1403050775, COSV62829784; called by muse, mutect2, varscan2
- MYL3 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.932); catalogued as COSV52768062; called by muse, mutect2
- NAA10 | c.624C>A p.D208E | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV63133014; called by muse, mutect2, varscan2
- NLRP12 | c.2894T>A p.L965Q | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60750121; called by muse, mutect2, varscan2
- NLRP14 | c.1537T>A p.S513T | Missense Mutation (SNP) | VAF 107/243 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV100205171; called by muse, mutect2, varscan2
- OAS2 | c.1398C>A p.S466R | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60803298; called by muse, mutect2, varscan2
- OGDH | c.2380C>A p.R794S | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56049352, COSV56052986; called by muse, mutect2, varscan2
- OR51B6 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 107/416 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV66513383; called by muse, mutect2, varscan2
- OR5K2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 132/688 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV101415963, COSV101415972; called by muse, mutect2, varscan2
- POU3F4 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV64539939; called by muse, mutect2, varscan2
- PTPRF | c.3963C>G p.Y1321* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV63446480; called by muse, mutect2, varscan2
- SCN7A | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101313280; called by muse, mutect2
- SLC4A10 | c.2490G>A p.M830I (on ENST00000446997 / NM_001354461.2; = p.M800I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55786734; called by muse, varscan2
- SVIL | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV63445163; called by muse, mutect2, varscan2
- SYNGAP1 | c.3116T>C p.I1039T | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs770078299, COSV53383312; called by muse, mutect2, varscan2
- SYT11 | c.635C>A p.T212N | Missense Mutation (SNP) | VAF 114/317 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64175281; called by muse, mutect2, varscan2
- TM6SF1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV51944993; called by muse, mutect2, varscan2
- TTN | c.35378C>T p.P11793L (on ENST00000591111; = p.P10866L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | PolyPhen probably damaging (0.998); catalogued as COSV60171626; called by muse, mutect2
- UNC5D | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as COSV54809811; called by muse, mutect2, varscan2
- VPS13B | c.9032T>A p.V3011D | Missense Mutation (SNP) | VAF 41/416 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV62136025, COSV62148243; called by muse, mutect2, varscan2
- WIPI2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV56589910; called by muse, mutect2, varscan2
- YWHAB | c.312C>G p.D104E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV62304495; called by muse, mutect2, varscan2
- ZMYM3 | c.2649C>A p.C883* | Nonsense Mutation (SNP) | VAF 70/390 reads (18%) | catalogued as COSV58739055; called by muse, mutect2, varscan2
- ZNF318 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.56); catalogued as rs761796412, COSV58934325; called by muse, mutect2, varscan2
- ZP2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV54812786; called by muse, mutect2, varscan2
- CORO6 | c.821_836delinsC p.Y274_S278del | In Frame Del (DEL) | VAF 25/47 reads (53%) | called by pindel, varscan2*
- FADS2 | c.1038_1043del p.E346_I347del | In Frame Del (DEL) | VAF 13/109 reads (12%) | called by pindel, varscan2
- FOXL1 | c.170_196del p.L57_A65del | In Frame Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel
- SLC22A10 | c.892_904del p.A298Lfs*7 | Frame Shift Del (DEL) | VAF 36/362 reads (10%) | called by mutect2, pindel
- ALMS1 | c.3651A>G p.K1217= | Silent (SNP) | VAF 105/434 reads (24%) | catalogued as COSV52514031; called by muse, mutect2, varscan2
- COL12A1 | c.6708A>G p.K2236= | Silent (SNP) | VAF 135/360 reads (38%) | catalogued as COSV59399986; called by muse, mutect2, varscan2
- FAM83B | c.2769T>G p.L923= | Silent (SNP) | VAF 103/308 reads (33%) | catalogued as COSV60924022; called by muse, mutect2, varscan2
- GABRR3 | c.348C>T p.D116= | Silent (SNP) | VAF 57/322 reads (18%) | catalogued as rs368459164, COSV72084168; called by muse, mutect2, varscan2
- KCTD20 | c.834A>T p.P278= | Silent (SNP) | VAF 52/161 reads (32%) | catalogued as COSV54803778; called by muse, mutect2, varscan2
- NAA15 | c.1047T>C p.Y349= | Silent (SNP) | VAF 13/336 reads (4%) | catalogued as COSV99649675; called by muse, mutect2
- NDST1 | c.1290G>A p.A430= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs1561601763, COSV55788581, COSV55791635; called by muse, mutect2, varscan2
- SCG2 | c.1350G>A p.T450= | Silent (SNP) | VAF 306/823 reads (37%) | catalogued as rs538546270, COSV59540803; called by muse, mutect2, varscan2
- SNTN | c.381C>A p.L127= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV59539162; called by muse, mutect2, varscan2
- TUT1 | c.180C>T p.V60= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99545424; called by muse, mutect2
- GCNT2 | c.926-34644G>T | Intron (SNP) | VAF 10/272 reads (4%) | catalogued as COSV99399402; called by muse, mutect2
- NBPF7 | n.848G>T | RNA (SNP) | VAF 49/121 reads (40%) | called by muse, mutect2, varscan2
